CCDI case PBBZDN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f08c26ef-fd7c-488c-b262-dc296fcf05b6

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 1.8 years (651 days).

Biospecimens (3 samples)
- Sample 0DL8PY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL8Q5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL8QI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
